Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6494, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6494-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODE
- C. PROSTATE

TCGA - G9 - 6494

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODE
- C. PROSTATE

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES:

Received fresh for frozen section is a tan pink fatty lymph node 1.5 x 1.2 x 0.6cm. The specimen is serially sectioned and submitted in toto in FSA.

B. LEFT PELVIC LYMPH NODES:

Received fresh for frozen section is a tan pink lymph node 0.5 x 0.5 x 0.5cm. The specimen is serially sectioned and submitted in toto in FSB.

C. PROSTATE:

Received fresh is an 85g resected prostate (7.0cm from left to right, 4.5cm from apex to base and 4.0cm from anterior to posterior), with attached right and left seminal vesicles and vas deferens. The capsule is tan pink smooth and intact. The specimen is inked as follows: Apex-Red, Anterior-Orange, Right Lateral-Green, Left Lateral-Yellow, Base-Blue, Posterior-Black. After removal of the apex and base, the remaining prostate weight is 54g. The specimen is serially sectioned from apex to base to reveal gray-white, firm, spongy tissue. A nodule is identified in level 1 1.2cm in greatest dimension. The attached right and left seminal vesicles are 3.5 x 1.5 x 1.0cm and 2.0 x 1.8 x 1.0cm, respectively, are sectioned to reveal beige tan cystic structure with no gross evidence of tumor involvement. The segments of right and left vas deferens are 3.0 x 0.6cm and 3.6 x 0.8cm respectively, and are sectioned to reveal beige tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (levels 1 & 3). The remainder of the specimen is submitted as follows:

- C1-C2: Right apex, perpendicular sections taken
- C3: Left apex, perpendicular section taken
- C4: level 1 right anterior capsule
- C5: level 1 right posterior capsule
- C6: level 1 left anterior capsule
- C7: level 1 left posterior capsule
- C8-C9: level 2 right anterior
- C10-C11: level 2 right posterior
- C12-C13: level 2 left anterior
- C14-C15: level 2 left posterior
- C16: level 3 right anterior capsule
- C17: level 3 right posterior capsule
- C18: level 3 left anterior capsule
- C19: level 3 left posterior capsule
- C20-C21: level 4 right anterior
- C22-C23: level 4 right posterior
- C24-C25: level 4 left anterior
- C26-C27: level 4 left posterior
- C28-C29: right base with periurethral margin, perpendicular sections taken
- C30-C31: left base with periurethral margin, perpendicular sections taken
- C32-C33: right lateral base
- C34-C35: left lateral base
- C36: right base
- C37: left base
- C38: reps of right seminal vesicle and vas deferens
- C39: reps of left seminal vesicle and vas deferens

DIAGNOSIS:

- A. RIGHT PELVIC LYMPH NODE, EXCISION:
- REACTIVE LYMPH NODE (0/1).

[page 2 of 3]
[REDACTED]

B. LEFT PELVIC LYMPH NODE, EXCISION:
- REACTIVE LYMPH NODE (0/1).

C. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA OF THE LEFT & RIGHT LOBES, GLEASON'S SCORE (4 + 3 = 7/10), INVADING THE ADIPOSE TISSUE AND THE BLADDER NECK.
- THE LEFT AND RIGHT BASE MARGINS ARE EXTENSIVELY INVOLVED BY CARCINOMA (SEE NOTE)
- SEE TEMPLATE.

Note: The bladder neck involvement is best seen in C30. The positive margins are seen on C28, C29, C30, and C32.

Dr. agreed on the bladder neck involvement.

SYNOPTIC REPORT - PROSTATE GLAND

Location: Left
Right
Posterior lateral
Basal
Anterior
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 40%
Gleason Grade/Sum:: Grade 4 + 3 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: Yes
Details: Right
Bladder Neck Involved: No
Margins Involvement: Yes
Location: left & right base
Linear Distance: Diffuse (>10mm or Multifocal)
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: Negative Right 0 / 1 Left 0 / 1
Other Pathologic Findings: None identified
Pathological Staging (pTNM): T 4 N 0 M x

PRE-OPERATIVE DIAGNOSIS:

Prostate Cancer.

INTRAOPERATIVE DIAGNOSIS:

FSA/FSB No tumor cells identified in two lymph nodes (0/2). Diagnosis called to Dr. at [REDACTED] by Dr.

ADDENDUM:

We are doing an addendum report due to a typographical error in the template:
Bladder neck involved should say "Yes" instead of "no".

[REDACTED]

Source: NCI Genomic Data Commons file 5b074ca7-f1b4-4cc4-83d2-d25b70764cb7 (TCGA-G9-6494.9AAD0222-0731-498B-A9C2-400CE0CCFA0D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).